MMRF case MMRF_2308 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c14ebb1c-a429-4954-a7d2-0fbbd2236e39

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 74 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 74.6 years (27,255 days); ISS stage: I; Days to last known disease status: 833 days (2.3 years); Days to last follow up: 833 days (2.3 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 12 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 13 days; Days to treatment end: 42 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 94 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 127 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -27 (ECOG 0): M Protein 3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.18 mg/dL; Immunoglobulin G 41.9 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 2.8 µg/mL; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 5.21 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 198 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.5 mmol/L; Albumin 43 g/L; Total Protein 10 g/dL; Glucose 5.34 mmol/L; C-Reactive Protein 0.82 mg/dL.
- Day 97 (ECOG 2): M Protein 3.1 g/dL; Immunoglobulin G 45.8 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 4.68 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 2.1 ×10⁹/L; Platelets 77 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.35 mmol/L; Albumin 45 g/L; Total Protein 9.6 g/dL; Glucose 5.28 mmol/L.
- Day 188 (ECOG 1): M Protein 2.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.504 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.17 mg/dL; Immunoglobulin G 36.8 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 2 ×10⁹/L; Absolute Neutrophil 0.6 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 59.2 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 8.5 g/dL; Glucose 4.95 mmol/L.
- Day 277 (ECOG 1): M Protein 2.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.486 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.08 mg/dL; Immunoglobulin G 34.1 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.11 g/L; Hemoglobin 7.13 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 8.5 g/dL; Glucose 5.28 mmol/L.
- Day 370 (ECOG 1): M Protein 2.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.555 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.15 mg/dL; Immunoglobulin G 34.1 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.38 mmol/L; Albumin 44 g/L; Total Protein 8.6 g/dL; Glucose 5.5 mmol/L.
- Day 463 (ECOG 1): M Protein 2.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.806 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.34 mg/dL; Immunoglobulin G 30.3 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 240 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 8.2 g/dL; Glucose 5.01 mmol/L.
- Day 552 (ECOG 1): M Protein 2.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.728 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.93 mg/dL; Immunoglobulin G 29.4 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.11 g/L; Hemoglobin 7.56 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 252 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 8.4 g/dL; Glucose 5.72 mmol/L.
- Day 637 (ECOG 1): M Protein 2.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.796 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.98 mg/dL; Immunoglobulin G 33.2 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 8.6 g/dL; Glucose 5.23 mmol/L.
- Day 734 (ECOG 1): M Protein 2.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.98 mg/dL; Immunoglobulin G 35.7 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.06 g/L; Hemoglobin 7.07 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 250 ×10⁹/L.
- Day 833 (ECOG 0): M Protein 3.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.02 mg/dL; Immunoglobulin G 39.5 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.06 g/L; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.2 mmol/L; Albumin 42 g/L; Total Protein 9.5 g/dL; Glucose 5.06 mmol/L.

Other clinical attributes
- Day -27: Weight: 47 kg; Height: 154 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (2 samples)
- Sample MMRF_2308_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -27 days.
- Sample MMRF_2308_1_PB_CD3pos: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -27 days.
